TCGA case TCGA-W5-AA31 — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2d6e20b2-82c7-4c12-92d0-93282b0a9031

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Alive.

Diagnoses (3)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 71.6 years (26,139 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 10 days; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Laterality: Left; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS.
3. Prior malignancy of the prostate gland (histology not recorded by GDC).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.

Follow-up (2 entries)
- Days to follow up: 10 days; Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 18 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 55.
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.1 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.2].
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.3].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1.1].
- Alpha Fetoprotein 4.4 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Platelets 151 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 105 kg; Height: 184 cm; BMI: 31.

Family history
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Testicular Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Gastric Cancer.
- Relatives with cancer history count: 2.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W5-AA31-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-W5-AA31-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-W5-AA31-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-W5-AA31-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-W5-AA31-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-W5-AA31-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Definitive surgical procedure: Extended Lobectomy.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.
- Other malignancy form 1, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Muscle; Other malignancy histological type: sarcoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 10 days; disease-specific survival: no event (censored), 10 days; disease-free interval: no event (censored), 10 days; progression-free interval: no event (censored), 10 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-W5-AA31-01A-11D-A416-01): tumor purity 0.47, ploidy 3.09, whole-genome doublings 1.
